Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A04N, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A04N-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex: (Age:) F Race: WHITE
Location:
Physician(s):

Specimen #: -

Taken:
Received:
Reported:

****AMENDED****

100-0-3
Carcinoma, infiltrating ductal, NOS 8500/
Site: breast, NOS C50.9
1/24/11
lu

SPECIMEN:

A: WIDE LOCAL EXCISION RIGHT BREAST B: SENT LN #1
C: SENT LN #2 D: SENT LN #1 (E: SENT LN #2 (
F: NONSENT LN #3

FINAL DIAGNOSIS:

- A. BREAST, RIGHT, WIDE LOCAL EXCISION:
- INVASIVE DUCTAL CARCINOMA, MODERATELY DIFFERENTIATED (BLOOM-RICHARDSON: TUBULAR FORMATION-2, NUCLEI-2, MITOSES-2 = 6), 1.7 CM, NEGATIVE FOR LYMPHOVASCULAR INVASION, MARGINS NEGATIVE.
- FIBROCYSTIC CHANGES TO INCLUDE CYSTS, FIBROSIS, APOCRINE METAPLASIA, AND DUCT ECTASIA.
- MULTIFOCAL FAT NECROSIS.
- ER/PR IMMUNOSTAINS ARE STRONGLY POSITIVE
- HER2-NEU OVEREXPRESSION BY FISH: NOT AMPLIFIED (1.2)
- B. LYMPH NODE, NON-SENTINAL #1, BIOPSY:
TWO LYMPH NODES NEGATIVE FOR MALIGNANCY (0/2).
- C. LYMPH NODE, NON-SENTINAL #2, BIOPSY:
TWO LYMPH NODES NEGATIVE FOR MALIGNANCY (0/2).
- D. LYMPH NODE, SENTINAL #1, BIOPSY:
NEGATIVE FOR MALIGNANCY BY IMMUNOHISTOCHEMICAL STAINS
- E. LYMPH NODE, SENTINAL #2, BIOPSY:
NEGATIVE FOR MALIGNANCY BY IMMUNOHISTOCHEMICAL STAINS
- F. LYMPH NODE, NON-SENTINAL #3, BIOPSY:
BENIGN ADIPOSE TISSUE, NO LYMPHOID TISSUE PRESENT.

PATHOLOGIC STAGING : T1c N0 MX

COMMENT:

CYTOKERATIN IS NEGATIVE IN SPECIMEN D AND E.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

**** Report Electronically Signed Out ****

=====

CLINICAL DIAGNOSIS AND HISTORY:

-year-old white female with 2.5 cm right outer mid breast tumor. Fine needle aspiration positive for atypical cells consistent with carcinoma.

FROZEN SECTION DIAGNOSIS:

A: RIGHT BREAST - INFILTRATING DUCTAL CARCINOMA

Results relayed to Dr.

in person.

GROSS DESCRIPTION:

A. WIDE LOCAL EXCISION RIGHT BREAST received fresh and consists of a piece of fatty tissue measuring 9.0 x 8.0 x 3.0 cm. The specimen is oriented with sutures by surgeon. Ink code: Red=medial lateral, blue=superior, green=inferior, yellow=anterior, black=posterior. Sectioning reveals a firm, tan, well-circumscribed mass, 1.7 cm in greatest dimension in the mid portion of the specimen; the mass is located 0.8 cm from the deep margin. A frozen section is prepared (block A1). There is a second well-circumscribed, tan nodule, 0.7 cm in diameter, located 0.5 cm superior anterior to the main mass. Sections harvested for breast protocol include (1) mass, OCT embedded (2) mass, flash frozen, and (3) grossly normal breast from the medial end of the specimen, flash frozen (matching paraffin sections=A1 and A2, respectively). Additional representative sections are submitted in sequential order from lateral to medial in cassettes A3 through A12. First mass in cassettes A1, A5, A6, A8, and the second mass in A7, A9, A10, and A11. 12CF

B. SENTINEL LYMPH NODE NUMBER ONE "NON-SENTINEL NODULE NUMBER ONE" received in formalin and consists of two irregular fragments of tan soft tissue with attached yellow adipose tissue measuring 2.0 and 1.7 cm in greatest dimension. The fragments are bisected and submitted in their entirety in two cassettes, one node per cassette. 2C4

C. SENTINEL LYMPH NODE NUMBER TWO "NON-SENTINEL NODE NUMBER TWO" received in formalin and consists of two irregular fragments of yellow, lobular adipose tissue measuring 2.5 cm in greatest dimension each. The fragments are bisected and submitted in their entirety in two cassettes, one fragment per cassette. 2C4

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

D. SENTINEL LYMPH NODE NUMBER ONE received in formalin and consists of one ovoid fragment of tan, fibrous tissue with attached yellow adipose tissue measuring 2.5 cm in greatest dimension. The specimen is serially sectioned and submitted in its entirety in two cassettes. 2C4

E. SENTINEL LYMPH NODE NUMBER TWO received in formalin and consists of a fragment of tan soft tissue measuring 2.5 cm in greatest dimension. The specimen is trisected and submitted in its entirety in two cassettes. 2C3

F. NON-SENTINEL LYMPH NODE NUMBER THREE received in formalin and consists of one ovoid fragment of tan soft tissue with adherent yellow adipose tissue measuring 1.7 cm in greatest dimension. The specimen is bisected and submitted in its entirety in one cassette. 1C2

Source: NCI Genomic Data Commons file 66e1574a-497e-401a-9ac3-890f508893c0 (TCGA-A2-A04N.45B4B99C-80E6-4AF4-8692-F7EE19D0467A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).